Gene-level copy-number profile of tumor specimen TCGA-24-1557-01A from TCGA case TCGA-24-1557, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.1 years (17,943 days).
Specimen TCGA-24-1557-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5cbc430f-495b-44e2-ac1c-5bcab1e43d22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1557-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b84c96c9-0745-47be-95cc-0291b308632a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,119; copy number 2: 19,372; copy number 3: 17,240; copy number 4: 16,157; copy number 5: 3,235; copy number 6: 962; copy number 7: 1,281; copy number 8: 288; copy number 9: 149; copy number 14: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1557-01): tumor purity 0.91, ploidy 3.24, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,844 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–5,090,899, 218 genes, copy number 5 (broad region; genes not listed).
- chr1:43,164,175–43,270,936, 1 gene, copy number 6 (within-gene range 4–6): EBNA1BP2.
- chr1:43,172,330–44,031,467, 38 genes, copy number 6 (within-gene range 4–6): CFAP57, RNA5SP46, TMEM125, C1orf210, TIE1, MPL, AL139289.2, AL139289.1, CDC20, ELOVL1, MIR6734, MED8, MED8-AS1, SZT2, SZT2-AS1, MIR6735, HYI, HYI-AS1, PTPRF, KDM4A, AL451062.2, KDM4A-AS1, ST3GAL3, ST3GAL3-AS1, U6, AL451062.1, MIR6079, SHMT1P1, ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2, CCDC24, SLC6A9.
- chr1:211,571,568–212,626,775, 38 genes, copy number 5: SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1, AC092803.3, NENF, LINC02771, AC092803.2, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A.
- chr1:228,449,163–230,282,122, 61 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:171,317,405–180,007,297, 183 genes, copy number 6–7 (broad region; genes not listed).
- chr2:185,652,374–213,284,205, 447 genes, copy number 5–7 (broad region; genes not listed).
- chr3:11,745–11,771,350, 161 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:148,791,102–149,086,554, 8 genes, copy number 7 (within-gene range 3–7): CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF.
- chr3:149,738,472–150,343,210, 20 genes, copy number 7: COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1.
- chr3:164,670,878–191,591,097, 448 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr4:6,320,578–12,948,670, 153 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–39,274,528, 610 genes, copy number 6–14 (within-gene range 4–14) (broad region; genes not listed).
- chr6:16,129,086–16,761,491, 10 genes, copy number 6 (within-gene range 3–6): MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1.
- chr7:103,471,784–103,989,658, 1 gene, copy number 5 (within-gene range 3–5): RELN.
- chr7:104,126,341–122,886,759, 235 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:150,584–2,623,382, 53 genes, copy number 5: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1.
- chr8:5,659,679–7,385,558, 62 genes, copy number 5 (broad region; genes not listed).
- chr8:32,927,913–43,674,591, 224 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:78,148,101–80,613,826, 47 genes, copy number 7: AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P.
- chr8:80,644,939–80,645,173, 1 gene, copy number 7: CKS1BP7.
- chr8:94,590,115–104,256,094, 213 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:109,240,919–145,066,685, 548 genes, copy number 5–9 (broad region; genes not listed).
- chr10:44,712–20,289,856, 338 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:31,784,779–38,500,186, 112 genes, copy number 5 (broad region; genes not listed).
- chr11:66,919,762–85,686,195, 484 genes, copy number 5 (broad region; genes not listed).
- chr11:101,029,624–101,129,813, 1 gene, copy number 5 (within-gene range 3–5): PGR.
- chr12:69,239,569–71,441,898, 39 genes, copy number 5: CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr13:70,459,464–103,444,968, 389 genes, copy number 5–7 (broad region; genes not listed).
- chr14:100,263,781–101,335,497, 143 genes, copy number 6 (broad region; genes not listed).
- chr15:92,567,817–92,620,015, 4 genes, copy number 5: LINC00930, AC091544.2, AC091544.4, AC091544.5.
- chr15:92,627,073–92,634,665, 2 genes, copy number 5: AC091544.3, AC091544.7.
- chr20:87,250–7,633,851, 206 genes, copy number 5–6 (broad region; genes not listed).
- chr20:36,306,336–37,317,260, 25 genes, copy number 6 (within-gene range 4–6): DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1, RBL1, RPS3AP3, RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2, GHRH, MANBAL.
- chr20:50,794,894–64,313,132, 321 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
